Somatic mutation profile of tumor specimen TCGA-YT-A95E-01A (aliquot TCGA-YT-A95E-01A-11D-A428-09) from TCGA case TCGA-YT-A95E, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 52.5 years (19,172 days).
Specimen TCGA-YT-A95E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a2b8c47-a491-445d-a4a3-ba282c4388f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YT-A95E-10A (Blood Derived Normal), aliquot TCGA-YT-A95E-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7839c553-bb62-4ab9-9c95-ba8ec89c906c

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 42/604 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CDC34 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.285); catalogued as COSV99198803; called by muse, mutect2
- HELZ2 | c.7565C>T p.T2522M (on ENST00000467148 / NM_001037335.2; = p.T1953M on NM_033405.3) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs561821964; called by muse, mutect2, varscan2
- MUC16 | c.10019C>A p.T3340N | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs947474864; called by muse, mutect2
- MYH9 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as CM147342, COSV53388606; called by muse, mutect2
- RBAK-RBAKDN | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV101208254; called by mutect2, varscan2
- WDR72 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382587777; called by muse, mutect2
- POLR3B | c.966+1G>C p.X322_splice | Splice Site (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- TP53BP2 | c.499C>A p.Q167K (on ENST00000343537 / NM_001031685.3; = p.Q38K on NM_005426.2) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- DPEP1 | c.9C>T p.S3= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs548760657, COSV55358842; called by mutect2, varscan2
- KCNH4 | c.1794C>T p.S598= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs752839564, COSV52915824; called by muse, mutect2, varscan2
